Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29N, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29N-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex
Location
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Series:

UUID: 08CCE4A2-2A10-4E4A-9DD2-2AASAE02A9E7

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Right axillary dissection for palpable metastatic disease.
Tissue submitted for tumour banking (fresh specimen).

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar Pathologist: A)

MACROSCOPIC DESCRIPTION

"RIGHT AXILLARY DISSECTION". Specimen consists of an irregular piece of fibrofatty tissue and attached muscle 155 x 85 x 40mm, the attached muscle is 100 x 50 x 10mm. The overlying skin ellipse (unoriented) measures 90 x 20mm and is unremarkable. There are 19 lymph nodes identified up to 25mm across. The largest lymph node has a tan white solid cut surface.

- A. Three lymph nodes.
- B-D. Three slices of the largest lymph node.
- E. Two lymph nodes.
- F & G. One bisected lymph node in each.
- H & I. One bisected lymph node.
- K-M. Two lymph nodes each.
- N. Three lymph nodes.
- P. One possible lymph node.
- Q. Two lymph nodes.
- R. Representative section from the centre of the skin.

1 CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary

C 77-3

hw 4/2/11

MICROSCOPIC REPORT

Dr

A total of 19 lymph nodes have been obtained from the axillary dissection. The largest lymph node identified macroscopically contains a 21mm deposit of metastatic melanoma (1B-1D). This lymph node is almost totally replaced by large epithelioid cells with pleomorphic vesicular nuclei, prominent nucleoli and abundant eosinophilic cytoplasm. Numerous mitoses, including atypical forms are seen. Some of the cells contain cytoplasmic melanin pigment. Foci of necrosis are also found. A small focus measuring 0.5mm of extranodal spread is seen (1C). No lymphovascular invasion is found. The atypical cells stain strongly with Melan A and HMB45 and weakly with S100. They stain negatively with CK.

The remaining lymph nodes show reactive changes of follicular hyperplasia and sinus histiocytosis, but no convincing evidence of malignancy is seen.

The section of overlying axillary skin contains an intradermal melanocytic naevus which appears completely excised by a distance of 1.7mm from the closest peripheral margin.

A Unit o

This fax was received by

Printed:

Page 1 of 2

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT**SUMMARY**

RIGHT AXILLARY DISSECTION : Metastatic melanoma in 1 out of 19 lymph nodes (1/19).

REPORTED BY

A Unit of

id:

Page 2 of 2

This fax was received by

Source: NCI Genomic Data Commons file 30a84436-187a-4995-a090-99638928c0cc (TCGA-EE-A29N.08CCE4A2-2A10-4E4A-9DD2-2AA5AE02A9E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).